Somatic mutation profile of tumor specimen MMRF_2654_1_BM_CD138pos (aliquot MMRF_2654_1_BM_CD138pos_T1_KHS5U_L13774) from MMRF case MMRF_2654, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow.
Specimen MMRF_2654_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6af1462a-cfc3-4b8b-a332-bb34c5d5beda.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2654_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2654_1_PB_WBC_C3_KHS5U_L13775; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/54e63b10-3d6b-47d3-bc7f-4a294f34c0f5

The open-access MAF lists 83 somatic variants for this specimen: 28 protein-altering or splice-affecting, 12 silent, 43 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 25, Missense Mutation 23, Silent 12, Intron 9, 3'Flank 4, 5'Flank 3, Nonsense Mutation 2, 5'UTR 2, Splice Site 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 24/73 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.493-2A>G p.X165_splice | Splice Site (SNP) | VAF 6/21 reads (29%) | catalogued as rs587781784, CS075218, COSV64297091, COSV64308401; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BSND | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as rs367549117; called by muse, mutect2, varscan2
- CCDC138 | c.1606C>A p.P536T | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs752800868; called by mutect2, varscan2
- CCNB3 | c.3781G>A p.A1261T | Missense Mutation (SNP) | VAF 67/92 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1340349955, COSV52069772, COSV52076569; called by muse, mutect2, varscan2
- CPXM2 | c.2212G>A p.V738I | Missense Mutation (SNP) | VAF 59/95 reads (62%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs761447450, COSV99580756; called by muse, mutect2, varscan2
- GDF5 | c.145G>T p.E49* | Nonsense Mutation (SNP) | VAF 57/140 reads (41%) | catalogued as COSV65503583; called by muse, mutect2, varscan2
- IGLL5 | c.126G>C p.M42I | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.003); catalogued as rs536568891; called by muse, mutect2, varscan2
- KIF7 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs898910099; called by muse, mutect2, varscan2
- LMO7 | c.2422G>C p.E808Q (on ENST00000357063; = p.E489Q on NM_005358.5) | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.255); catalogued as COSV58529796; called by muse, mutect2
- MALL | c.77T>G p.I26S | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs762996235; called by muse, mutect2, varscan2
- NCLN | c.545A>G p.N182S | Missense Mutation (SNP) | VAF 113/296 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.09); catalogued as rs745739355; called by muse, mutect2, varscan2
- PIGT | c.944A>G p.Y315C | Missense Mutation (SNP) | VAF 27/235 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1339969567; called by muse, mutect2, varscan2
- POU4F3 | c.617C>G p.A206G | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV57942694; called by muse, mutect2, varscan2
- RTP1 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV56617942, COSV56618257; called by muse, mutect2, varscan2
- TRANK1 | c.1840C>T p.Q614* | Nonsense Mutation (SNP) | VAF 116/263 reads (44%) | catalogued as rs922565983; called by muse, mutect2, varscan2
- ARHGAP31 | c.4052G>C p.S1351T | Missense Mutation (SNP) | VAF 56/189 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- COIL | c.1489-1G>A p.X497_splice | Splice Site (SNP) | VAF 26/71 reads (37%) | called by muse, mutect2, varscan2
- IGLV4-3 | c.155_167del p.I52Nfs*11 | Frame Shift Del (DEL) | VAF 66/191 reads (35%) | called by mutect2, varscan2
- KATNA1 | c.976A>C p.S326R | Missense Mutation (SNP) | VAF 49/133 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MATN4 | c.1460C>T p.A487V (on ENST00000372754; = p.A446V on NM_003833.4) | Missense Mutation (SNP) | VAF 63/153 reads (41%) | PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MYLK | c.1735G>A p.G579S | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDE12 | c.424T>C p.W142R | Missense Mutation (SNP) | VAF 123/269 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SCN7A | c.709C>G p.L237V | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- SLC16A12 | c.289G>A p.V97M | Missense Mutation (SNP) | VAF 9/152 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.029); called by muse, mutect2
- SPAG17 | c.6515T>A p.F2172Y | Missense Mutation (SNP) | VAF 130/313 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- WDR87 | c.7648T>C p.C2550R | Missense Mutation (SNP) | VAF 82/206 reads (40%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- ZNF287 | c.57G>T p.R19S | Missense Mutation (SNP) | VAF 89/237 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACAD8 | c.15C>T p.G5= | Silent (SNP) | VAF 16/146 reads (11%) | called by muse, mutect2, varscan2
- ADGRL4 | c.1248T>C p.G416= | Silent (SNP) | VAF 50/148 reads (34%) | called by muse, mutect2, varscan2
- COL14A1 | c.2259A>T p.V753= | Silent (SNP) | VAF 84/200 reads (42%) | called by muse, mutect2, varscan2
- DBH | c.360G>A p.K120= | Silent (SNP) | VAF 26/65 reads (40%) | called by muse, mutect2, varscan2
- DUSP2 | c.163C>T p.L55= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as rs1205324747; called by muse, mutect2, varscan2
- ENPP1 | c.148C>T p.L50= | Silent (SNP) | VAF 21/38 reads (55%) | catalogued as rs1389275450; called by muse, mutect2, varscan2
- EPN1 | c.591G>A p.E197= | Silent (SNP) | VAF 18/42 reads (43%) | called by muse, mutect2, varscan2
- IGHV3-33 | c.342C>T p.Y114= | Silent (SNP) | VAF 58/146 reads (40%) | catalogued as rs772022074; called by muse, varscan2
- MGAT1 | c.429C>T p.C143= | Silent (SNP) | VAF 75/256 reads (29%) | called by muse, mutect2, varscan2
- OLFML1 | c.159G>A p.T53= | Silent (SNP) | VAF 60/136 reads (44%) | catalogued as rs747718879, COSV61403770; called by muse, mutect2, varscan2
- PCDHGB2 | c.2274A>G p.S758= | Silent (SNP) | VAF 16/143 reads (11%) | called by muse, mutect2, varscan2
- RHBG | c.582C>T p.L194= | Silent (SNP) | VAF 50/144 reads (35%) | catalogued as rs370053677; called by muse, mutect2, varscan2
- ACSBG1 | c.132-4556C>T | Intron (SNP) | VAF 35/109 reads (32%) | catalogued as rs1455611442; called by muse, mutect2, varscan2
- ARHGAP5 | c.*2835G>A | 3'UTR (SNP) | VAF 7/70 reads (10%) | called by muse, mutect2, varscan2
- ARMH4 | c.*1520G>A | 3'UTR (SNP) | VAF 44/95 reads (46%) | called by muse, mutect2, varscan2
- B3GAT2 | c.*279G>C | 3'UTR (SNP) | VAF 46/118 reads (39%) | called by muse, mutect2, varscan2
- BEND3 | c.*687C>T | 3'UTR (SNP) | VAF 61/171 reads (36%) | catalogued as rs1375857087; called by muse, mutect2, varscan2
- BLNK | c.-114G>C | 5'UTR (SNP) | VAF 65/192 reads (34%) | called by muse, mutect2, varscan2
- CACNG4 | c.*82C>T | 3'UTR (SNP) | VAF 8/33 reads (24%) | catalogued as rs909612209, COSV100047864; called by muse, mutect2, varscan2
- CCDC18 | chr1:93278595 T>C | 3'Flank (SNP) | VAF 51/126 reads (40%) | called by muse, mutect2, varscan2
- CD226 | c.*1330T>G | 3'UTR (SNP) | VAF 38/107 reads (36%) | called by muse, mutect2, varscan2
- CXCL5 | c.*1242G>A | 3'UTR (SNP) | VAF 62/142 reads (44%) | called by muse, mutect2, varscan2
- EMP2 | c.*4066G>T | 3'UTR (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- ETV5 | c.-65T>G | 5'UTR (SNP) | VAF 128/304 reads (42%) | called by muse, mutect2, varscan2
- FAM131B | c.-56-899C>T | Intron (SNP) | VAF 25/104 reads (24%) | catalogued as rs948596723; called by muse, mutect2, varscan2
- FBXO44 | c.*1519T>C | 3'UTR (SNP) | VAF 19/40 reads (48%) | called by muse, mutect2, varscan2
- FTO | c.*1285G>C | 3'UTR (SNP) | VAF 84/211 reads (40%) | called by muse, mutect2, varscan2
- FZD5 | c.*567A>G | 3'UTR (SNP) | VAF 44/105 reads (42%) | called by muse, mutect2, varscan2
- GABRB2 | c.*4905G>C | 3'UTR (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
- HOMER3 | c.*98G>T | 3'UTR (SNP) | VAF 29/71 reads (41%) | called by muse, mutect2, varscan2
- ITPRID1 | c.-19-3539A>G | Intron (SNP) | VAF 25/90 reads (28%) | called by muse, mutect2, varscan2
- KBTBD3 | c.*283C>T | 3'UTR (SNP) | VAF 23/63 reads (37%) | called by muse, mutect2, varscan2
- LINC01235 | n.508+86C>T | Intron (SNP) | VAF 15/56 reads (27%) | catalogued as rs1171335965; called by muse, mutect2, varscan2
- LTB | c.163-135C>T | Intron (SNP) | VAF 121/303 reads (40%) | called by muse, mutect2, varscan2
- MARCHF6 | c.*1109C>T | 3'UTR (SNP) | VAF 14/55 reads (25%) | called by muse, mutect2, varscan2
- METTL15 | c.*956T>G | 3'UTR (SNP) | VAF 28/82 reads (34%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851289 T>G | 5'Flank (SNP) | VAF 87/213 reads (41%) | catalogued as rs1283772994; called by muse, mutect2, varscan2
- MIR5195 | chr14:106851350 C>T | 5'Flank (SNP) | VAF 70/162 reads (43%) | called by muse, mutect2, varscan2
- MPV17 | c.71-13G>A | Intron (SNP) | VAF 39/126 reads (31%) | catalogued as rs780618131; called by muse, mutect2, varscan2
- MYB | c.*733G>A | 3'UTR (SNP) | VAF 13/35 reads (37%) | called by muse, mutect2, varscan2
- NEGR1 | c.*219dup | 3'UTR (INS) | VAF 20/59 reads (34%) | catalogued as rs796980896; called by mutect2, varscan2
- NET1 | c.*717T>C | 3'UTR (SNP) | VAF 9/16 reads (56%) | called by muse, mutect2, varscan2
- NIPSNAP2 | c.374-13A>G | Intron (SNP) | VAF 102/203 reads (50%) | called by muse, mutect2, varscan2
- NPAS3 | chr14:33802540 A>G | 3'Flank (SNP) | VAF 21/65 reads (32%) | called by muse, mutect2, varscan2
- PCSK5 | c.2626+3513A>T | Intron (SNP) | VAF 120/244 reads (49%) | called by muse, mutect2, varscan2
- PLCXD3 | c.*1386G>A | 3'UTR (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- POU2F2 | chr19:42088861 G>A | 3'Flank (SNP) | VAF 66/160 reads (41%) | called by muse, mutect2, varscan2
- PREPL | chr2:44318528 C>G | 3'Flank (SNP) | VAF 11/38 reads (29%) | called by muse, mutect2, varscan2
- PROS1 | c.*173C>A | 3'UTR (SNP) | VAF 74/199 reads (37%) | called by muse, mutect2, varscan2
- RALYL | c.-24+761T>A | Intron (SNP) | VAF 22/56 reads (39%) | called by muse, mutect2, varscan2
- RGS7BP | c.*1078G>A | 3'UTR (SNP) | VAF 26/74 reads (35%) | called by muse, mutect2, varscan2
- RXFP2 | c.*223A>T | 3'UTR (SNP) | VAF 45/65 reads (69%) | called by muse, mutect2, varscan2
- TTLL7 | c.*1541T>G | 3'UTR (SNP) | VAF 43/95 reads (45%) | called by muse, mutect2, varscan2
- ZBTB37 | chr1:173866304 T>G | 5'Flank (SNP) | VAF 39/82 reads (48%) | called by muse, mutect2, varscan2
- ZFHX3 | c.*2846C>T | 3'UTR (SNP) | VAF 17/49 reads (35%) | catalogued as rs550308551; called by muse, mutect2, varscan2
